Somatic mutation profile of tumor specimen TCGA-23-1809-01A (aliquot TCGA-23-1809-01A-01W-0633-09) from TCGA case TCGA-23-1809, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 63.3 years (23,111 days).
Specimen TCGA-23-1809-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd468d94-cfcb-49ff-adcc-dcfeaeb89f1c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1809-10A (Blood Derived Normal), aliquot TCGA-23-1809-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecd8bd91-be31-4928-9946-13e6eeb74982

The open-access MAF lists 56 somatic variants for this specimen: 44 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 11, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM19 | c.2375G>A p.R792Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs138014472; called by muse, mutect2, varscan2
- ATP10B | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs1372642678, COSV59148108; called by muse, mutect2, varscan2
- CEP170 | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 96/181 reads (53%) | catalogued as rs1419190758, COSV60507980; called by muse, mutect2, varscan2
- CRB1 | c.2188G>A p.D730N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66329415; called by muse, mutect2, varscan2
- CRB1 | c.2309G>C p.G770A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM130792, COSV66329420; called by muse, mutect2, varscan2
- DCAF12L2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV63583759; called by muse, mutect2
- DCTD | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63866841; called by muse, mutect2, varscan2
- ELP3 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs190129217; called by muse, mutect2, varscan2
- EMILIN1 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777144262, COSV53154177; called by muse, mutect2, varscan2
- EPHX2 | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 87/120 reads (73%) | SIFT tolerated (0.25); PolyPhen benign (0.225); catalogued as COSV66844482; called by muse, mutect2, varscan2
- FCRL4 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs200366937, COSV54861364; called by muse, mutect2, varscan2
- FGD1 | c.2597G>A p.R866H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as COSV64308489; called by muse, mutect2, varscan2
- GNPAT | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 24/118 reads (20%) | catalogued as COSV64153242, COSV64153474; called by muse, mutect2, varscan2
- INSM2 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs201878584; called by mutect2, varscan2
- INTU | c.1510G>A p.D504N | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777216506, COSV58870684; called by muse, mutect2, varscan2
- KRT19 | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 26/32 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54178876; called by muse, mutect2, varscan2
- LRRFIP1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200515993, COSV57827565; called by muse, mutect2, varscan2
- MARCHF4 | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV56104261; called by muse, mutect2, varscan2
- MRGPRD | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs900414568, COSV58422659; called by muse, mutect2, varscan2
- MVK | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747116992, CM010934, COSV57331644; called by muse, mutect2, varscan2
- NBN | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs1554563922, COSV55372395; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCAM2 | c.599A>T p.D200V | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.927); catalogued as COSV53066884; called by muse, mutect2, varscan2
- OR2A4 | c.769A>T p.M257L | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as COSV59575803; called by muse, mutect2, varscan2
- OR2L3 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV63454958, COSV63455786; called by muse, mutect2, varscan2
- OR4N2 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 210/718 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60050810; called by muse, mutect2, varscan2
- OR8B3 | c.584A>T p.N195I | Missense Mutation (SNP) | VAF 58/193 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV63541558, COSV63541932; called by muse, mutect2, varscan2
- PODXL | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV59869641; called by muse, mutect2, varscan2
- PTPN3 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs777977887, COSV52702848; called by muse, mutect2, varscan2
- PTPRH | c.3005T>C p.M1002T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV54744357; called by muse, mutect2, varscan2
- SEC31A | c.2605C>A p.P869T (on ENST00000355196 / NM_001318120.1; = p.P830T on NM_016211.4) | Missense Mutation (SNP) | VAF 75/102 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV52343794; called by muse, mutect2, varscan2
- SLC25A15 | c.617A>G p.E206G | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV58556907; called by muse, mutect2, varscan2
- STYXL2 | c.3128G>A p.R1043H | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs373097210; called by muse, mutect2, varscan2
- TBC1D8B | c.1108C>T p.R370C | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs769746560, COSV52176794; called by muse, mutect2, varscan2
- TDRD1 | c.2575G>C p.A859P | Missense Mutation (SNP) | VAF 59/76 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52589487; called by muse, mutect2, varscan2
- TIMM9 | c.197G>C p.R66T | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53621405; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 100/146 reads (68%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- UBN2 | c.3351G>A p.M1117I | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV56029424, COSV99944018; called by muse, mutect2, varscan2
- USH2A | c.12359G>A p.R4120H | Missense Mutation (SNP) | VAF 135/214 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs188008529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR49 | c.1350G>T p.E450D (on ENST00000308378 / NM_001366158.1; = p.E791D on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV57705933; called by muse, mutect2, varscan2
- ZFHX3 | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs762462194, COSV51714442; called by muse, mutect2, varscan2
- ZNF24 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 33/324 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.869); catalogued as COSV54348278; called by muse, mutect2, varscan2
- ADCY8 | c.2293_2296del p.K765Vfs*29 | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by mutect2, pindel, varscan2
- KHDRBS2 | c.748dup p.A250Gfs*16 | Frame Shift Ins (INS) | VAF 9/105 reads (9%) | called by mutect2, pindel
- KMT5B | c.663del p.N221Kfs*4 | Frame Shift Del (DEL) | VAF 33/74 reads (45%) | called by mutect2, pindel, varscan2
- ACTL7A | c.123C>T p.A41= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs570985989, COSV100453065, COSV61776474; called by muse, mutect2, varscan2
- DGKG | c.2052G>A p.R684= | Silent (SNP) | VAF 25/636 reads (4%) | catalogued as COSV99402462; called by muse, mutect2
- DSC2 | c.1086A>G p.T362= | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV51862974, COSV99199950; called by muse, mutect2, varscan2
- ESM1 | c.357A>G p.S119= | Silent (SNP) | VAF 12/127 reads (9%) | catalogued as COSV101195595, COSV67318295; called by muse, mutect2
- HNRNPA3 | c.834C>T p.G278= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs768986881, COSV66820730; called by muse, mutect2, varscan2
- ITPR3 | c.1953C>G p.L651= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV65407805; called by muse, mutect2, varscan2
- NEB | c.7900C>T p.L2634= | Silent (SNP) | VAF 172/252 reads (68%) | catalogued as COSV51086361; called by muse, mutect2, varscan2
- USP11 | c.2379C>A p.T793= (on ENST00000218348; = p.T750= on NM_001371072.1) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99510707; called by muse, mutect2
- USP11 | c.2380C>T p.L794= (on ENST00000218348; = p.L751= on NM_001371072.1) | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99510709; called by muse, mutect2
- ZBTB3 | c.1209G>A p.L403= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs780023432, COSV67361088; called by muse, mutect2, varscan2
- ZNF404 | c.1335A>G p.G445= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as rs779090814, COSV60986894; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505101 del TGGAGTAACTGGCATGTGAGCAAACTGTGTTGGCGTGGGGG | 5'Flank (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel
